Somatic mutation profile of tumor specimen TCGA-B3-4104-01A (aliquot TCGA-B3-4104-01A-01D-1458-08) from TCGA case TCGA-B3-4104, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 75.9 years (27,709 days).
Specimen TCGA-B3-4104-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28514760-c92f-4649-a2e4-80e7841262e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B3-4104-10A (Blood Derived Normal), aliquot TCGA-B3-4104-10A-01D-1458-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1150ac8-e290-45e1-827a-7212595bbad9

The open-access MAF lists 84 somatic variants for this specimen: 59 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 22, Nonsense Mutation 6, Frame Shift Del 2, Splice Site 1, Translation Start Site 1, 3'Flank 1, Splice Region 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.272G>A p.W91* | Nonsense Mutation (SNP) | VAF 22/128 reads (17%) | hotspot (GDC flag); catalogued as COSV52734595, COSV53139118; called by muse, mutect2, varscan2
- ALDH1B1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs774671053, COSV66619506; called by muse, mutect2
- C9orf24 | c.135G>A p.P45= | Splice Region (SNP) | VAF 88/298 reads (30%) | catalogued as rs757617269; called by muse, mutect2, varscan2
- CACNG4 | c.827T>C p.M276T | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs762265124; called by muse, mutect2, varscan2
- CCNL2 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs750408739; called by muse, varscan2
- CHRM2 | c.444G>T p.W148C | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57778241; called by muse, mutect2, varscan2
- DSC2 | c.1420C>G p.P474A | Missense Mutation (SNP) | VAF 214/403 reads (53%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs1354317356; called by muse, mutect2, varscan2
- EPN3 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99277596; called by muse, mutect2, varscan2
- IDE | c.172C>G p.P58A | Missense Mutation (SNP) | VAF 85/202 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs1445075843, COSV56423511; called by muse, mutect2, varscan2
- IL9R | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs372322566, COSV54899166; called by muse, mutect2, varscan2
- KMT2C | c.5929C>T p.Q1977* | Nonsense Mutation (SNP) | VAF 105/667 reads (16%) | catalogued as COSV51454142, COSV99030560; called by muse, mutect2, varscan2
- KMT2D | c.12649C>T p.Q4217* | Nonsense Mutation (SNP) | VAF 29/70 reads (41%) | catalogued as COSV56407982; called by muse, mutect2, varscan2
- LHFPL4 | c.643+2C>T p.X215_splice | Splice Site (SNP) | VAF 154/340 reads (45%) | catalogued as rs747204949; called by muse, mutect2, varscan2
- MACC1 | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1378592841; called by muse, mutect2, varscan2
- MLH3 | c.1469C>G p.S490C | Missense Mutation (SNP) | VAF 130/342 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.24); catalogued as COSV53153789, COSV99469879; called by muse, mutect2, varscan2
- MRTFA | c.1775C>T p.S592L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs199908950, COSV62932756; called by muse, mutect2, varscan2
- PCDHGA12 | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); catalogued as rs775284049, COSV52752225; called by muse, mutect2, varscan2
- PCDHGA3 | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 136/294 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); catalogued as rs756507522, COSV53902134, COSV54032096; called by muse, mutect2, varscan2
- PLEKHG5 | c.2654G>A p.R885Q (on ENST00000400915 / NM_001042663.3; = p.R848Q on NM_020631.6) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs761000380, COSV61069337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAPGEF3 | c.1223C>T p.S408F (on ENST00000389212; = p.S366F on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1435656137; called by muse, mutect2, varscan2
- SHE | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1335015387; called by muse, mutect2
- SMPD2 | c.454del p.R152Vfs*40 | Frame Shift Del (DEL) | VAF 97/267 reads (36%) | catalogued as COSV57806697; called by mutect2, pindel, varscan2
- STAG2 | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 81/93 reads (87%) | catalogued as COSV54364707; called by muse, mutect2, varscan2
- THRAP3 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 81/181 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs148045717; called by muse, mutect2, varscan2
- TRIML1 | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs765434450, COSV60195900; called by muse, mutect2, varscan2
- UNC5C | c.1768C>A p.P590T | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV71662581; called by muse, mutect2, varscan2
- VLDLR | c.2395G>A p.A799T | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.306); catalogued as rs183359461; called by muse, varscan2
- VWCE | c.2831C>T p.P944L | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs951052952; called by muse, mutect2, varscan2
- ZDHHC7 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 117/263 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs758226485, COSV58212654; called by muse, mutect2, varscan2
- APLNR | c.142C>G p.L48V | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- ARRB1 | c.905C>G p.S302C | Missense Mutation (SNP) | VAF 156/344 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ATP1A1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 91/236 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- BRD2 | c.2036C>G p.S679* | Nonsense Mutation (SNP) | VAF 43/98 reads (44%) | called by muse, mutect2, varscan2
- CFAP65 | c.2992G>A p.E998K | Missense Mutation (SNP) | VAF 89/158 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.255); called by muse, varscan2
- CLINT1 | c.450G>C p.K150N | Missense Mutation (SNP) | VAF 74/152 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CORO1B | c.993del p.K331Nfs*20 | Frame Shift Del (DEL) | VAF 60/150 reads (40%) | called by mutect2, pindel, varscan2
- CPXM1 | c.1983G>T p.W661C | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTCFL | c.1139G>C p.R380T | Missense Mutation (SNP) | VAF 237/539 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- EPN3 | c.759G>C p.E253D | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ERLIN2 | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 25/538 reads (5%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.822); called by muse, mutect2
- EXOSC9 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 65/161 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GABRB3 | c.1172C>G p.S391* | Nonsense Mutation (SNP) | VAF 115/251 reads (46%) | called by muse, mutect2, varscan2
- ITGAE | c.1211T>A p.I404N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.107); called by muse, varscan2
- KRT13 | c.925A>T p.T309S | Missense Mutation (SNP) | VAF 179/412 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- MACF1 | c.19289G>C p.R6430T (on ENST00000372915; = p.R4475T on NM_012090.5) | Missense Mutation (SNP) | VAF 46/104 reads (44%) | called by muse, mutect2, varscan2
- MS4A15 | c.467T>A p.I156N (on ENST00000405633 / NM_001098835.2; = p.I63N on NM_152717.3) | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- OR14J1 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 154/398 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PICK1 | c.1074C>G p.F358L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PRKAG2 | c.608G>C p.R203T | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- RIC8A | c.209T>A p.V70D | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- SGMS1 | c.839A>G p.Y280C | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SLC38A10 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 67/317 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPATA20 | c.1147G>A p.E383K (on ENST00000356488 / NM_001258372.1; = p.E399K on NM_022827.4) | Missense Mutation (SNP) | VAF 186/417 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- STARD10 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- TEX2 | c.2800G>C p.E934Q (on ENST00000583097 / NM_001288733.2; = p.E941Q on NM_018469.5) | Missense Mutation (SNP) | VAF 664/953 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- TYRP1 | c.1184C>A p.P395Q | Missense Mutation (SNP) | VAF 106/363 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR41 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2
- WDR59 | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- XPR1 | c.1909G>C p.D637H | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- BRD2 | c.1635C>G p.P545= | Silent (SNP) | VAF 35/87 reads (40%) | called by muse, mutect2, varscan2
- CCNL2 | c.231C>T p.L77= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs374243154, COSV100784949; called by muse, varscan2
- CELSR1 | c.2076C>T p.Y692= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs529594359, COSV53090406; called by muse, mutect2, varscan2
- DBF4B | c.1290C>T p.L430= | Silent (SNP) | VAF 59/127 reads (46%) | catalogued as COSV100154457; called by muse, mutect2, varscan2
- EFHB | c.2052C>G p.L684= | Silent (SNP) | VAF 83/184 reads (45%) | catalogued as COSV55546191; called by muse, mutect2, varscan2
- ETAA1 | c.1485A>G p.Q495= | Silent (SNP) | VAF 43/84 reads (51%) | catalogued as rs971704214; called by muse, mutect2, varscan2
- FGFR3 | c.927C>T p.L309= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs1405842619, COSV53416517, COSV53427150; called by muse, mutect2, varscan2
- FKBP3 | c.85C>T p.L29= | Silent (SNP) | VAF 47/139 reads (34%) | called by muse, mutect2, varscan2
- FLT4 | c.2043G>A p.T681= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as rs1325289784, COSV56115106; called by muse, mutect2, varscan2
- INSM2 | c.1590C>T p.C530= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as rs774497773, COSV51897847; called by muse, mutect2, varscan2
- MISP | c.723C>T p.N241= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as rs754864934, COSV53119471; called by muse, mutect2, varscan2
- NEB | c.15648G>A p.L5216= | Silent (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- NEBL | c.186C>T p.F62= | Silent (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- OR4S2 | c.333C>T p.F111= | Silent (SNP) | VAF 20/596 reads (3%) | called by muse, mutect2
- PARVB | c.1074C>T p.T358= | Silent (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- PIK3R2 | c.1890G>A p.T630= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs965191886; called by muse, mutect2, varscan2
- PRAMEF1 | c.660G>C p.L220= | Silent (SNP) | VAF 481/985 reads (49%) | called by muse, mutect2, varscan2
- SPATA20 | c.1362G>A p.Q454= (on ENST00000356488 / NM_001258372.1; = p.Q470= on NM_022827.4) | Silent (SNP) | VAF 60/135 reads (44%) | called by muse, varscan2
- ST7L | c.780A>G p.A260= | Silent (SNP) | VAF 99/211 reads (47%) | called by muse, mutect2, varscan2
- TDRD10 | c.249G>A p.V83= | Silent (SNP) | VAF 34/361 reads (9%) | called by muse, mutect2
- ZBTB46 | c.1045C>T p.L349= | Silent (SNP) | VAF 94/198 reads (47%) | called by muse, mutect2, varscan2
- ZFP36L1 | c.918G>C p.L306= | Silent (SNP) | VAF 75/184 reads (41%) | catalogued as rs1392960726, COSV60547607; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055981 G>A | 3'Flank (SNP) | VAF 63/147 reads (43%) | called by muse, mutect2, varscan2
- PRR12 | c.52-258G>A | Intron (SNP) | VAF 6/17 reads (35%) | catalogued as rs774901947, COSV69820179; called by muse, mutect2, varscan2
- SNORD116-1 | n.89G>C | RNA (SNP) | VAF 87/185 reads (47%) | called by muse, mutect2, varscan2
